Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A1CS, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A1CS-01A (Primary Tumor).

[page 1 of 2]
Carcinoma, Papillary, Thyroid 8260/3
Site Code: Thyroid, NOS C73.9 1/9/11
lw

Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Service:

Visit #:

Accession #:

Collected:

Received:

Gender: F

HCN:

Ordering MD:

Copy To:

Location:

Facility:

Reported:

Specimen(s) Received

1. Lymph-Node: Right paratracheal lymph node
2. Thyroid: Total thyroid and right paratracheal node stitch right upper lobe for tumour bnkng

Diagnosis

1. No pathological diagnosis: Lymph nodes, 4 (right paratracheal) dissection specimen
2. Multifocal papillary carcinoma, dominant 1.3 cm, left; underlying mild nodular hyperplasia: Thyroid
No pathological diagnosis: Lymph nodes, 2
- Total thyroidectomy specimen

Synoptic Data

Specimen Type:	Other: Total thyroidectomy & right paratracheal dissection
Tumour Focality:	Multifocal
-----Dominant Tumour-----	
Histologic Type:	Papillary carcinoma, classical type
Tumour Site:	Left Lobe
Tumour Size:	Greatest Dimension: 1.3 cm
	Additional Dimensions: 1.1 x 1.1 cm
Capsular Invasion:	Encapsulated
Extrathyroidal Extension:	Locally invasive
Margins:	Absent
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Absent
-----Secondary Tumour-----	
Histologic Type:	Papillary carcinoma, follicular variant
Tumour Site:	Right Lobe
Tumour Size:	Greatest Dimension: 0.5cm
Capsular Invasion:	Unencapsulated
	Non-invasive
Extrathyroidal Extension:	Absent
Margins:	Margins uninvolved by carcinoma
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Absent

Pathologic Staging (pTNM):	pT1: Tumor size 2 cm or less, limited to thyroid

Diagnostic Discrepancy		X
Case Incomplete		X

[page 2 of 2]
Surgical Pathology Consultation Report

pN0: No regional lymph node metastasis
Number of regional lymph nodes examined: 6
Number of regional lymph nodes involved: 0
pMX: Distant metastasis cannot be assessed

Additional Pathologic Findings: Nodular hyperplasia
Thyroiditis
Other (specify): additional multiple papillary microcarcinomas

Electronically verified by:

Gross Description

1. The specimen container labeled with the patient's name and as "Lymph Node: Right paratracheal lymph node" contains a fragment of red-yellow tissue that measures 0.8 x 0.6 x 0.3 cm.
1A submitted in toto
2. The specimen labeled with the patient's name and as "Thyroid: Total thyroid and right paratracheal node" consists of a thyroid gland that weighs 18.05 g. The right lobe measures 4.3 cm SI x 2.5 cm ML x 1.3 cm AP, the left lobe measures 4.5 cm SI x 2.3 cm ML x 2.1 cm AP and the isthmus measures 2.0 cm SI x 1.0 cm ML x 0.8 cm AP. The external surfaces have fibrous adhesions. No parathyroid glands or lymph nodes are identified grossly. The external surface is painted with blue dye. The lower left lobe contains a well delineated nodule that measures 1.1 cm SI x 1.3 cm ML x 1.1 cm AP. The remainder of the thyroid tissue is unremarkable. Sections of left lobe nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:
-F right lobe, superior to inferior
isthmus
2H-N left lobe, superior to inferior

Source: NCI Genomic Data Commons file a6dde464-9685-4a95-8e07-97d2b2d4fbb4 (TCGA-EM-A1CS.225D9285-DFDA-426E-B1C5-5A557272B552.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).